Somatic mutation profile of tumor specimen TCGA-LN-A9FO-01A (aliquot TCGA-LN-A9FO-01A-11D-A387-09) from TCGA case TCGA-LN-A9FO, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 42.6 years (15,551 days).
Specimen TCGA-LN-A9FO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bca43a67-ecff-4995-9d33-e8736e2445dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LN-A9FO-10A (Blood Derived Normal), aliquot TCGA-LN-A9FO-10A-01D-A38A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e659c72-308d-468b-8f94-7e7115972111

The open-access MAF lists 97 somatic variants for this specimen: 73 protein-altering or splice-affecting, 22 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 22, Nonsense Mutation 4, Frame Shift Ins 2, Splice Site 2, RNA 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTA1 | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as COSV64203934; called by muse, mutect2
- ADCY8 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs773742788, COSV53896347; called by muse, mutect2, varscan2
- ADGRB2 | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as rs1247649143, COSV57071400; called by muse, mutect2, varscan2
- ARAP3 | c.4213G>A p.E1405K | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.971); catalogued as rs1219970163; called by muse, mutect2, varscan2
- DNAH5 | c.7544C>T p.T2515M | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as COSV54224881; called by muse, mutect2, varscan2
- ENTHD1 | c.1487A>G p.N496S | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1390300214; called by muse, mutect2, varscan2
- FAM91A1 | c.475A>G p.I159V | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1436221774; called by muse, mutect2, varscan2
- KDM5C | c.3533C>T p.S1178L | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs370672146; called by muse, mutect2, varscan2
- NYAP2 | c.1327G>C p.G443R | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV99796518; called by muse, mutect2, varscan2
- OR2B2 | c.349G>C p.V117L | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.275); catalogued as COSV57579810, COSV57580640; called by muse, mutect2, varscan2
- PCDHB3 | c.1518C>G p.I506M | Missense Mutation (SNP) | VAF 54/243 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as rs1392738799, COSV50563898; called by muse, mutect2, varscan2
- PDZK1 | c.484G>C p.D162H | Missense Mutation (SNP) | VAF 62/189 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs782182897; called by muse, mutect2, varscan2
- PLEC | c.7855G>C p.E2619Q (on ENST00000322810 / NM_201380.4; = p.E2509Q on NM_000445.5) | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.051); catalogued as COSV100511273, COSV59697468; called by muse, mutect2, varscan2
- PLEC | c.7785G>C p.E2595D (on ENST00000322810 / NM_201380.4; = p.E2485D on NM_000445.5) | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV59644046; called by muse, mutect2, varscan2
- SGK2 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs369635262; called by muse, mutect2, varscan2
- SP2 | c.1756G>A p.E586K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as rs771830248, COSV100947189; called by muse, mutect2, varscan2
- SSC4D | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs148308343; called by muse, mutect2, varscan2
- SUMF2 | c.653A>G p.K218R (on ENST00000652303; = p.K199R on NM_015411.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as rs754025668; called by muse, mutect2, varscan2
- TDRD1 | c.2824A>G p.I942V | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs376481564; called by muse, mutect2, varscan2
- TENM4 | c.6388A>G p.I2130V | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as rs749341010; called by muse, mutect2, varscan2
- TP53 | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 41/60 reads (68%) | catalogued as COSV52679869, COSV53267121, COSV53424574; called by muse, mutect2, varscan2
- TTN | c.2744G>A p.R915H (on ENST00000591111; = p.R869H on NM_003319.4) | Missense Mutation (SNP) | VAF 12/54 reads (22%) | PolyPhen benign (0); catalogued as rs376922544, COSV60235359; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- ZC3H4 | c.1110C>T p.D370= | Splice Region (SNP) | VAF 23/53 reads (43%) | catalogued as rs1198294182, COSV99452180; called by muse, mutect2, varscan2
- ZNF831 | c.313G>A p.V105M | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.034); catalogued as rs371038563, COSV64046403; called by muse, mutect2
- ADAM19 | c.2657G>T p.G886V | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALG1 | c.391-1G>A p.X131_splice | Splice Site (SNP) | VAF 22/53 reads (42%) | called by muse, varscan2
- AVPR1A | c.1110G>T p.K370N | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC151 | c.811G>C p.E271Q | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CCDC65 | c.246G>C p.E82D | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- CFAP46 | c.637T>C p.Y213H | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- CNST | c.1672G>C p.D558H | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- CXCR4 | c.486C>G p.I162M | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- DAXX | c.1969G>C p.E657Q | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.006); called by muse, mutect2
- DCAF13 | c.521G>A p.C174Y | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- DHX8 | c.1681C>T p.Q561* | Nonsense Mutation (SNP) | VAF 23/52 reads (44%) | called by muse, mutect2, varscan2
- EIF4ENIF1 | c.2786C>T p.P929L | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- FAT3 | c.5857C>A p.L1953M | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- FBN2 | c.425G>A p.G142E | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- GNB5 | c.841G>A p.E281K (on ENST00000261837 / NM_016194.4; = p.E239K on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- KLHL4 | c.829A>T p.K277* | Nonsense Mutation (SNP) | VAF 18/63 reads (29%) | called by muse, mutect2, varscan2
- KRT77 | c.1282C>A p.L428M | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- LPGAT1 | c.461C>G p.S154C | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- LRRC4B | c.1708G>A p.D570N | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- MYCBP2 | c.12181G>C p.D4061H (on ENST00000357337; = p.D4099H on NM_015057.5) | Missense Mutation (SNP) | VAF 47/68 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- NAP1L4 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 48/75 reads (64%) | SIFT tolerated (0.33); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- NBEAL1 | c.6625G>C p.E2209Q | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NLRP1 | c.4236G>C p.Q1412H (on ENST00000572272 / NM_033004.4; = p.Q1368H on NM_014922.5) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- NME7 | c.140dup p.L47Ffs*7 | Frame Shift Ins (INS) | VAF 6/41 reads (15%) | called by mutect2, pindel, varscan2
- NOP58 | c.319A>T p.I107F | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NUP153 | c.85T>G p.Y29D | Missense Mutation (SNP) | VAF 57/116 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- OPTN | c.798G>C p.K266N | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.238); called by muse, mutect2
- OVCA2 | c.230A>T p.E77V | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- P2RX2 | c.174-16_174-2delinsTGC p.X58_splice (on ENST00000343948 / NM_170683.4; = p.X36_splice on NM_012226.5) | Splice Site (DEL) | VAF 15/54 reads (28%) | called by pindel, varscan2*
- PCDHGC5 | c.1948G>T p.D650Y | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- POMZP3 | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 48/152 reads (32%) | called by muse, mutect2, varscan2
- PRDM9 | c.2429G>T p.G810V | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- RMND1 | c.45A>G p.I15M | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- RNF111 | c.1976A>G p.H659R | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RUSC2 | c.4445G>C p.G1482A | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT tolerated (0.91); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SIX4 | c.1802G>T p.G601V | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.567); called by muse, mutect2, varscan2
- SLITRK4 | c.847G>C p.G283R | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLITRK5 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2
- SPATA7 | c.156G>A p.M52I | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SPG11 | c.4901C>G p.S1634C | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- SUN2 | c.1064dup p.Q356Pfs*186 | Frame Shift Ins (INS) | VAF 19/30 reads (63%) | called by mutect2, pindel, varscan2
- TAF1B | c.1633C>G p.L545V | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- TECPR2 | c.3893A>G p.E1298G | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- TENT5D | c.338C>A p.P113Q | Missense Mutation (SNP) | VAF 36/43 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- THBS2 | c.1154C>G p.S385C | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- TMEM97 | c.247A>G p.I83V | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- UBE2K | c.346C>G p.L116V | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT deleterious (0.03); PolyPhen benign (0.235); called by muse, varscan2
- ZFYVE26 | c.5528G>A p.C1843Y | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ZNF223 | c.1291G>C p.E431Q | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ACSS3 | c.1530T>C p.P510= | Silent (SNP) | VAF 38/115 reads (33%) | called by muse, mutect2, varscan2
- ANO4 | c.2364C>G p.V788= (on ENST00000392977 / NM_001286615.2; = p.V753= on NM_178826.4) | Silent (SNP) | VAF 9/63 reads (14%) | called by muse, mutect2, varscan2
- ATP11B | c.1350A>G p.L450= | Silent (SNP) | VAF 52/137 reads (38%) | called by muse, mutect2, varscan2
- CCDC61 | c.201C>T p.F67= | Silent (SNP) | VAF 6/138 reads (4%) | catalogued as COSV99625589; called by muse, mutect2
- GPR135 | c.1125G>A p.L375= | Silent (SNP) | VAF 5/87 reads (6%) | called by muse, mutect2
- GRIN3A | c.378C>T p.D126= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs1189653238; called by mutect2, varscan2
- H1-2 | c.633G>A p.K211= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs750505144, COSV59189690; called by muse, mutect2, varscan2
- HFM1 | c.4117C>T p.L1373= | Silent (SNP) | VAF 44/139 reads (32%) | called by muse, mutect2, varscan2
- HIVEP2 | c.6045A>G p.R2015= | Silent (SNP) | VAF 22/42 reads (52%) | called by muse, mutect2, varscan2
- NAALAD2 | c.474C>A p.G158= | Silent (SNP) | VAF 77/136 reads (57%) | called by muse, mutect2, varscan2
- PCDHA9 | c.2295G>A p.Q765= | Silent (SNP) | VAF 38/85 reads (45%) | catalogued as COSV65331021; called by muse, mutect2, varscan2
- PDZD7 | c.1233G>A p.A411= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs1356340580; called by muse, mutect2, varscan2
- PTPN9 | c.435G>A p.Q145= | Silent (SNP) | VAF 29/61 reads (48%) | called by muse, mutect2, varscan2
- RAPGEF5 | c.237G>A p.K79= (on ENST00000401957 / NM_001367602.2; = p.K382= on NM_012294.5) | Silent (SNP) | VAF 11/34 reads (32%) | called by muse, mutect2, varscan2
- RFX7 | c.3270T>C p.N1090= (on ENST00000559447 / NM_001368074.1; = p.N1187= on NM_022841.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/30 reads (60%) | called by muse, mutect2, varscan2
- RPF1 | c.891C>T p.F297= | Silent (SNP) | VAF 25/39 reads (64%) | catalogued as COSV65706058; called by muse, mutect2, varscan2
- SEC16B | c.1803T>G p.T601= | Silent (SNP) | VAF 16/93 reads (17%) | called by muse, mutect2, varscan2
- SEC31A | c.390G>C p.V130= | Silent (SNP) | VAF 26/45 reads (58%) | called by muse, mutect2, varscan2
- TMBIM4 | c.432A>G p.Q144= | Silent (SNP) | VAF 27/106 reads (25%) | catalogued as rs946126721; called by muse, mutect2, varscan2
- UNG | c.822G>A p.Q274= (on ENST00000242576 / NM_080911.3; = p.Q265= on NM_003362.4) | Silent (SNP) | VAF 38/122 reads (31%) | called by muse, mutect2, varscan2
- ZNF341 | c.1869A>G p.K623= (on ENST00000375200 / NM_001282935.1; = p.K616= on NM_032819.4) | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as rs958980694; called by muse, mutect2, varscan2
- ZNF568 | c.105C>T p.S35= | Silent (SNP) | VAF 39/102 reads (38%) | catalogued as rs975214439, COSV61741652; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505743 G>C | 5'Flank (SNP) | VAF 7/63 reads (11%) | catalogued as rs373484523; called by muse, mutect2, varscan2
- SSPOP | n.4287G>T | RNA (SNP) | VAF 18/51 reads (35%) | catalogued as rs540269082; called by muse, mutect2, varscan2
